Gene-level copy-number profile of tumor specimen TCGA-DU-6403-01A from TCGA case TCGA-DU-6403, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 60.3 years (22,031 days).
Specimen TCGA-DU-6403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.d5635350-61c0-460c-a6e9-5ce7a4347475.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6403-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11a646d1-db26-4c18-b0e6-e6a4811bc3a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,788; copy number 2: 52,758; copy number 3: 2,609; copy number 4: 536; copy number 12: 36; copy number 13: 20; copy number 17: 38; copy number 22: 17; copy number 26: 8; copy number 31: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6403-01A-11D-1704-01): tumor purity 0.71, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,765,177–204,728,106, 38 genes, copy number 17: LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr7:51,471,717–53,188,938, 13 genes, copy number 26–31 (within-gene range 4–31): AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:54,330,670–55,260,256, 17 genes, copy number 22: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr12:57,610,180–58,105,935, 36 genes, copy number 12: ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr22:24,011,192–24,629,005, 20 genes, copy number 13 (within-gene range 2–13): CABIN1, AC253536.3, SUSD2, GGT5, GGTLC4P, POM121L9P, BCRP1, AP000354.1, SPECC1L, SPECC1L-ADORA2A, ADORA2A, ADORA2A-AS1, UPB1, AP000355.1, GUCD1, SNRPD3, AP000356.5, LRRC75B, GGT1, AP000356.1.

Autosomal genes at a single copy (total copy number 1): 3,788. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
